Gene-level copy-number profile of tumor specimen TCGA-L5-A4OJ-01A from TCGA case TCGA-L5-A4OJ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 70.2 years (25,657 days).
Specimen TCGA-L5-A4OJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.b2c2750d-1823-4c73-9b24-99f2aa28059f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OJ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/63957443-0fa2-40a4-ade5-dcd3d5c256bc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 2: 8,713; copy number 3: 4,039; copy number 4: 44,707; copy number 5: 355; copy number 6: 3; copy number 7: 1,399; copy number 8: 76; copy number 9: 31; copy number 12: 126; copy number 13: 2; copy number 15: 90; copy number 17: 16; copy number 19: 22; copy number 20: 5; copy number 21: 21; copy number 23: 53; copy number 26: 5; copy number 29: 26; copy number 35: 22; copy number 39: 48; copy number 42: 4; copy number 75: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OJ-01A-11D-A25X-01): tumor purity 0.78, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,809,269–59,811,310, 1 gene: AC093418.1.
- chr10:75,742,740–75,743,755, 1 gene: AL731568.1.
- chr16:78,495,926–78,553,296, 4 genes (within-gene range 0–2): AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 518 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:52,891,837–57,837,046, 172 genes, copy number 12–75 (broad region; genes not listed).
- chr8:2,923,568–2,926,689, 1 gene, copy number 19: AC023296.1.
- chr8:3,373,353–3,700,628, 3 genes, copy number 19: AC026991.1, AC026991.2, RNA5SP251.
- chr8:5,659,679–8,226,614, 126 genes, copy number 9–20 (within-gene range 9–33) (broad region; genes not listed).
- chr8:9,984,004–12,388,296, 95 genes, copy number 9–39 (broad region; genes not listed).
- chr8:123,319,850–123,416,350, 1 gene, copy number 23 (within-gene range 4–23): ATAD2.
- chr8:123,348,034–126,292,788, 53 genes, copy number 17–29 (within-gene range 4–29): MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861.
- chr8:125,951,861–128,564,679, 41 genes, copy number 23–29: SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr17:68,259,182–68,422,731, 1 gene, copy number 9 (within-gene range 4–9): ARSG.
- chr17:68,413,623–69,553,865, 25 genes, copy number 9: AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
